Somatic mutation profile of tumor specimen 0DMBGW from CCDI case PBBZUJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,096 days).
Specimen 0DMBGW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eeeea857-13eb-47cf-be70-89373d1d07fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBGX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dede0f8f-1c3a-41f8-92b6-5e309e6021ad

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Intron 3, Splice Site 3, Nonsense Mutation 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3469C>T p.R1157W | Missense Mutation (SNP) | VAF 201/526 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM122495, COSV60789213; called by muse, mutect2, varscan2
- B3GNT2 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 22/393 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1265416776; called by muse, mutect2
- BRD9 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 44/517 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs769494561; called by muse, mutect2
- CAND2 | c.2032G>A p.A678T (on ENST00000456430 / NM_001162499.2; = p.A585T on NM_012298.3) | Missense Mutation (SNP) | VAF 92/467 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.042); catalogued as rs779143752, COSV99928971; called by muse, mutect2, varscan2
- CNTNAP1 | c.1735+1G>A p.X579_splice | Splice Site (SNP) | VAF 34/542 reads (6%) | catalogued as rs1159275615, COSV52855740; called by muse, mutect2
- DNAI3 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 211/1468 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs544660942; called by muse, mutect2, varscan2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 100/731 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- ELFN1 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.105); catalogued as rs767496054; called by muse, mutect2, varscan2
- ENPP5 | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 177/778 reads (23%) | catalogued as COSV57909306, COSV57909682; called by muse, mutect2, varscan2
- HTR1E | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 165/812 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs185147794; called by muse, mutect2, varscan2
- JADE3 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 178/439 reads (41%) | catalogued as COSV54466078; called by muse, mutect2, varscan2
- JAKMIP1 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1002730678; called by muse, mutect2
- LRRC4C | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 84/1202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347112092, COSV53417483; called by muse, mutect2
- TREH | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 27/463 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs371520320; called by muse, mutect2
- ZBTB18 | c.1261T>C p.C421R | Missense Mutation (SNP) | VAF 47/549 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62397731; called by muse, mutect2
- ZNF215 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 126/1707 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545734774, COSV99549948; called by muse, mutect2
- ARHGEF7 | c.734-2A>T p.X245_splice (on ENST00000375741 / NM_001113511.2; = p.X67_splice on NM_003899.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 123/688 reads (18%) | called by muse, mutect2, varscan2
- DENND6A | c.1826_*1del | Nonstop Mutation (DEL) | VAF 105/787 reads (13%) | called by mutect2, pindel, varscan2
- EPHB4 | c.2041G>A p.G681S | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLI3 | c.3647T>A p.L1216H | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2
- HMG20B | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LLGL2 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- LRCH2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 177/207 reads (86%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCBP2L | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 128/387 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR4A1 | c.876+1G>A p.X292_splice | Splice Site (SNP) | VAF 46/285 reads (16%) | called by muse, mutect2, varscan2
- RINT1 | c.2134C>T p.L712F | Missense Mutation (SNP) | VAF 99/1577 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM184A | c.574G>C p.V192L | Missense Mutation (SNP) | VAF 29/445 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.346); called by muse, mutect2
- ZNF587 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 80/1742 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- KRT6B | c.951C>T p.S317= | Silent (SNP) | VAF 191/1096 reads (17%) | catalogued as rs377079859, COSV52886721; called by muse, mutect2, varscan2
- MRGPRX3 | c.546G>C p.A182= | Silent (SNP) | VAF 44/572 reads (8%) | catalogued as rs147746956; called by muse, mutect2
- MYBL2 | c.1161C>T p.G387= | Silent (SNP) | VAF 89/425 reads (21%) | called by muse, mutect2, varscan2
- NLRP4 | c.2484C>T p.C828= | Silent (SNP) | VAF 72/790 reads (9%) | catalogued as rs373707796; called by muse, mutect2
- SHANK2 | c.891C>T p.N297= | Silent (SNP) | VAF 75/545 reads (14%) | catalogued as rs782183599, COSV58317998; called by muse, mutect2, varscan2
- TASOR2 | c.1950T>A p.V650= | Silent (SNP) | VAF 30/1134 reads (3%) | called by muse, mutect2
- TNS3 | c.1368C>T p.H456= | Silent (SNP) | VAF 90/574 reads (16%) | catalogued as rs780611654; called by muse, mutect2, varscan2
- MYO15B | c.2436-102T>G | Intron (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- SLC6A13 | c.696+79G>A | Intron (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- SP140 | c.2361+92C>T | Intron (SNP) | VAF 36/791 reads (5%) | catalogued as rs1157113819; called by muse, mutect2
